Somatic mutation profile of tumor specimen TCGA-UF-A718-01A (aliquot TCGA-UF-A718-01A-22D-A34J-08) from TCGA case TCGA-UF-A718, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.5 years (22,836 days).
Specimen TCGA-UF-A718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87fd60c2-24d6-4559-9c10-9b5631ee7616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A718-10A (Blood Derived Normal), aliquot TCGA-UF-A718-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fd9e0fe-0b1c-4abe-81b5-3c26885227dc

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Frame Shift Ins 4, Splice Site 3, Nonsense Mutation 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 52/100 reads (52%) | hotspot (GDC flag); catalogued as CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; called by muse, mutect2, varscan2
- ACP7 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs754476691, COSV58699744; called by muse, mutect2, varscan2
- CARD8 | c.308G>A p.R103H (on ENST00000651546 / NM_001184900.3; = p.R53H on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs536343060, COSV100751133; called by muse, mutect2, varscan2
- CDYL2 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101629586; called by muse, mutect2, varscan2
- CENPL | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100616372; called by muse, mutect2, varscan2
- CEP170B | c.4271G>T p.R1424L (on ENST00000453495; = p.R1353L on NM_015005.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99229822; called by muse, varscan2
- CEP290 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV58350742; called by muse, mutect2, varscan2
- CFAP69 | c.2740A>T p.K914* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV100290203; called by muse, mutect2, varscan2
- CHPF | c.1763A>T p.Q588L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99705040; called by muse, mutect2, varscan2
- COL19A1 | c.2937C>G p.I979M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.574); catalogued as COSV100506515; called by muse, mutect2, varscan2
- CR2 | c.1721T>G p.I574S | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889661; called by muse, mutect2, varscan2
- CYLC1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.17); catalogued as COSV100254841; called by muse, mutect2, varscan2
- DHX38 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs753500280, COSV99194345; called by muse, mutect2, varscan2
- DNMT3A | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs1290621612, COSV99262859; called by muse, varscan2
- DPH5 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV100587368; called by muse, mutect2, varscan2
- EIF4B | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100016846; called by muse, mutect2, varscan2
- EXOSC5 | c.525+1G>T p.X175_splice | Splice Site (SNP) | VAF 49/209 reads (23%) | catalogued as COSV99652692; called by muse, mutect2, varscan2
- FOXL2NB | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100374534, COSV100374616; called by muse, mutect2, varscan2
- HFM1 | c.3106G>T p.A1036S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.135); catalogued as rs377647325, COSV99646146; called by muse, mutect2, varscan2
- HFM1 | c.3105C>A p.D1035E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54036743, COSV99646149; called by muse, mutect2, varscan2
- KIF4B | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs781281000, COSV70526976; called by muse, mutect2, varscan2
- KMT2B | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs376006013, COSV99719373, COSV99719835; called by muse, varscan2
- LTBP4 | c.4224dup p.A1409Rfs*3 (on ENST00000308370 / NM_001042544.1; = p.A1372Rfs*3 on NM_003573.2) | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | catalogued as rs754757253; called by mutect2, varscan2
- MCTP1 | c.2876A>T p.D959V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100387440; called by muse, mutect2, varscan2
- MET | c.1966-1G>T p.X656_splice | Splice Site (SNP) | VAF 40/182 reads (22%) | catalogued as COSV100577246; called by muse, mutect2, varscan2
- MLH3 | c.1364A>C p.E455A | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99465083; called by muse, mutect2, varscan2
- MYH8 | c.868dup p.Y290Lfs*7 | Frame Shift Ins (INS) | VAF 28/139 reads (20%) | catalogued as rs1319380590; called by mutect2, pindel, varscan2
- NDUFB2 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV99199976; called by muse, mutect2, varscan2
- PCDH11X | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs1346767103, COSV100012390; called by muse, mutect2, varscan2
- PCDHA4 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV63542477; called by muse, varscan2
- PIGQ | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as rs752737257, COSV50312258; called by muse, mutect2, varscan2
- PLA2G7 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99221439; called by muse, mutect2, varscan2
- PRRC2C | c.4921C>A p.P1641T (on ENST00000367742; = p.P1639T on NM_015172.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs773951826, COSV58911209; called by muse, mutect2, varscan2
- SCUBE1 | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV99298292; called by muse, mutect2, varscan2
- SLC22A23 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100978260; called by muse, mutect2, varscan2
- SLC35F5 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99830093; called by muse, mutect2, varscan2
- SMARCA4 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as rs917552239, COSV100758080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG7 | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV100750373; called by muse, mutect2, varscan2
- TMEM198 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99524901; called by muse, varscan2
- TPP2 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV101060308; called by muse, mutect2, varscan2
- UNKL | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs145589979; called by muse, mutect2, varscan2
- WWOX | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101283090, COSV68345001; called by muse, mutect2, varscan2
- XBP1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273888, COSV99321699; called by muse, mutect2, varscan2
- ZNF43 | c.1415A>T p.H472L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100731844; called by muse, mutect2, varscan2
- C15orf39 | c.926dup p.H310Pfs*75 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- OGDH | c.2847dup p.N950Qfs*3 | Frame Shift Ins (INS) | VAF 31/145 reads (21%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.1168del p.R390Dfs*26 (on ENST00000400457 / NM_032973.2; = p.R379Dfs*26 on NM_032971.3) | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- KATNIP | c.4563C>T p.D1521= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs370236727; called by muse, mutect2, varscan2
- LRP1B | c.12735A>T p.G4245= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV101257803; called by muse, mutect2, varscan2
- LYZL2 | c.378C>T p.F126= (on ENST00000375318; = p.F80= on NM_183058.3) | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV64684090; called by muse, mutect2, varscan2
- PSMA8 | c.81G>T p.A27= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs570532077, COSV100378604, COSV57601056; called by muse, mutect2, varscan2
- SEC14L1 | c.1053C>G p.T351= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101171067; called by muse, mutect2, varscan2
- SLC1A6 | c.1674A>T p.G558= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99693844; called by muse, mutect2
- SLC25A6 | c.804G>A p.K268= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as rs1349395155, COSV100452306; called by muse, varscan2
- SUPT20H | c.537A>C p.S179= (on ENST00000350612 / NM_001014286.3; = p.S180= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100634720; called by muse, mutect2, varscan2
- TXNDC11 | c.924G>A p.A308= (on ENST00000356957 / NM_001303447.2; = p.A281= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs373925712; called by muse, mutect2, varscan2
- ZEB1 | c.3066G>C p.S1022= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100314548, COSV58035771; called by mutect2, varscan2
- MIR122 | n.85C>G | RNA (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
